Somatic mutation profile of tumor specimen MBCProject_0595_T1_WES (aliquot MBCProject_0595_T1_WES_1) from CMI case MBCProject_0595, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_0595_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a0cffb4-93c1-435d-98ff-dad09e6f10c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0595_SALIVA (Saliva), aliquot MBCProject_0595_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78182c09-7364-41da-9856-183ee5c0ee14

The open-access MAF lists 67 somatic variants for this specimen: 41 protein-altering or splice-affecting, 13 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, Intron 7, 5'UTR 4, Nonsense Mutation 3, Splice Site 2, In Frame Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K4 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62254615; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 32/62 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 109/193 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C4orf54 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs1449601420; called by muse, mutect2
- CDH1 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs373605261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP11A1 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs375479754; called by muse, mutect2, varscan2
- EBF3 | c.877C>T p.Q293* (on ENST00000355311 / NM_001375392.1; = p.Q284* on NM_001005463.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as rs1421064481; called by muse, mutect2, varscan2
- LYPD4 | c.113G>C p.R38T | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs368266342, COSV58027855; called by muse, mutect2
- MRGPRX2 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs1166014845, COSV61674413; called by muse, mutect2, varscan2
- PRPS1L1 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV72650015; called by muse, mutect2
- PSG11 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV60454747; called by muse, varscan2
- RFPL4A | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as rs777645016, COSV70455635, COSV70455694; called by muse, mutect2, varscan2
- SYTL3 | c.805C>T p.L269F (on ENST00000611299 / NM_001242394.1; = p.L201F on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.223); catalogued as rs1221674261, COSV51912688; called by mutect2, varscan2
- TMEM126B | c.304G>C p.D102H | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as COSV100729070; called by muse, mutect2, varscan2
- ABHD10 | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALS2CL | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AR | c.1156C>G p.R386G | Missense Mutation (SNP) | VAF 53/452 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLASP2 | c.3739G>A p.D1247N (on ENST00000359576; = p.D1246N on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- COL6A5 | c.3302G>T p.G1101V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- DMBT1 | c.5851G>C p.D1951H (on ENST00000338354 / NM_001377530.1; = p.D1194H on NM_004406.3) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- FREM3 | c.6265G>T p.D2089Y | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HADH | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- HMCN1 | c.1705A>G p.R569G | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- JMY | c.2428_2463del p.T810_P821del | In Frame Del (DEL) | VAF 7/47 reads (15%) | called by mutect2, varscan2*
- KRT72 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 111/308 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMB1 | c.4455G>C p.K1485N | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- LPAR3 | c.304T>A p.W102R | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MYO5A | c.4906C>T p.Q1636* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- PCDHA5 | c.2212C>G p.L738V | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PIEZO2 | c.1665G>C p.L555F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PRPF31 | c.1147-1G>C p.X383_splice | Splice Site (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- PSG2 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PTPRZ1 | c.4201G>A p.E1401K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); called by mutect2, varscan2
- RABGAP1L | c.1204G>T p.V402L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- RBM20 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 27/314 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.623); called by muse, mutect2
- SIPA1 | c.2440G>C p.D814H | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.28); called by muse, mutect2
- SNRPG | c.182T>C p.V61A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- SPAG9 | c.2618-1G>C p.X873_splice (on ENST00000262013 / NM_001130528.3; = p.X859_splice on NM_003971.6) | Splice Site (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- TMC8 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TXLNA | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBE2D4 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- APC2 | c.5319G>A p.K1773= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs1268241595; called by muse, mutect2, varscan2
- ARFGEF2 | c.3882C>T p.I1294= | Silent (SNP) | VAF 18/121 reads (15%) | called by muse, varscan2
- C17orf97 | c.249G>A p.R83= | Silent (SNP) | VAF 35/217 reads (16%) | called by muse, mutect2, varscan2
- CSMD2 | c.522C>T p.H174= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs749023926, COSV53912233, COSV53919670; called by muse, mutect2, varscan2
- EFHD1 | c.261C>T p.F87= | Silent (SNP) | VAF 20/266 reads (8%) | called by muse, mutect2
- EHMT2 | c.1500C>T p.F500= | Silent (SNP) | VAF 12/80 reads (15%) | called by muse, varscan2
- EPSTI1 | c.694A>C p.R232= (on ENST00000398762 / NM_001330543.2; = p.R221= on NM_033255.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, varscan2
- FBN1 | c.4305C>T p.F1435= | Silent (SNP) | VAF 27/157 reads (17%) | catalogued as rs1243628683, COSV57317372; called by muse, mutect2, varscan2
- H1-2 | c.33C>T p.A11= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs539669898, COSV59190735; called by mutect2, varscan2
- KAZN | c.2265C>T p.P755= | Silent (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- MTHFSD | c.9G>C p.P3= | Silent (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- SEMA6B | c.387C>T p.F129= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs765059242, COSV100014787; called by mutect2, varscan2
- SPTLC2 | c.1002G>A p.K334= | Silent (SNP) | VAF 45/171 reads (26%) | called by muse, mutect2, varscan2
- AK7 | c.2134-276T>C | Intron (SNP) | VAF 8/55 reads (15%) | catalogued as rs1334656460; called by muse, varscan2
- C15orf40 | c.366+132T>C | Intron (SNP) | VAF 6/13 reads (46%) | catalogued as rs1210782920, COSV58449491; called by mutect2, varscan2
- C17orf99 | c.640+114G>A | Intron (SNP) | VAF 16/125 reads (13%) | called by muse, mutect2, varscan2
- MAGEA11 | c.-5G>A | 5'UTR (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- MIR487B | n.18G>T | RNA (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- NLRP2 | c.281-393A>G | Intron (SNP) | VAF 5/29 reads (17%) | catalogued as rs752108162; called by muse, mutect2
- OXR1 | c.-29G>C | 5'UTR (SNP) | VAF 5/49 reads (10%) | catalogued as COSV101471686; called by muse, mutect2, varscan2
- RMI2 | c.-8G>A | 5'UTR (SNP) | VAF 7/63 reads (11%) | catalogued as rs963308396, COSV100434942; called by muse, mutect2
- RPN2 | chr20:37179245 C>T | 5'Flank (SNP) | VAF 41/126 reads (33%) | called by muse, mutect2, varscan2
- SLC4A9 | c.2898+24C>G | Intron (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- STIM2 | c.-72C>T | 5'UTR (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- TG | c.7239+29042G>A | Intron (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- TUBGCP2 | c.616+586A>G | Intron (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2
